Somatic mutation profile of tumor specimen TCGA-92-8064-01A (aliquot TCGA-92-8064-01A-11D-2244-08) from TCGA case TCGA-92-8064, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; Age at diagnosis: 58.6 years (21,417 days).
Specimen TCGA-92-8064-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49998b43-7c95-429a-b0ad-e1c24ce7d3a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-92-8064-10A (Blood Derived Normal), aliquot TCGA-92-8064-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bd2a860-f176-4e27-81a4-6ca5800b8575

The open-access MAF lists 234 somatic variants for this specimen: 178 protein-altering or splice-affecting, 47 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 47, Nonsense Mutation 14, Frame Shift Del 8, Splice Site 6, Intron 5, Frame Shift Ins 2, RNA 2, Splice Region 2, 5'Flank 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.237G>T p.E79D | Missense Mutation (SNP) | VAF 14/44 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1057519924, COSV67962147; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.236A>G p.E79G | Missense Mutation (SNP) | VAF 15/46 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960135, COSV67960407, COSV67962953; called by muse, mutect2, varscan2
- A2ML1 | c.2704C>A p.L902I | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as rs1195893094; called by muse, mutect2, varscan2
- ADGRE1 | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as COSV51678768; called by muse, mutect2, varscan2
- AGT | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761670478, COSV100794198; called by muse, mutect2
- ARHGEF1 | c.1268-2A>C p.X423_splice | Splice Site (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100528838; called by muse, mutect2, varscan2
- BRCA2 | c.7507G>C p.V2503L | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV66451402, COSV66463407; called by muse, mutect2, varscan2
- CASKIN2 | c.2818C>T p.P940S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs746864464; called by muse, varscan2
- CCL21 | c.383C>A p.S128* | Nonsense Mutation (SNP) | VAF 27/136 reads (20%) | catalogued as rs1370944166; called by muse, mutect2, varscan2
- CDH11 | c.1359G>T p.W453C | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51770173, COSV51771651; called by muse, mutect2, varscan2
- CEP170 | c.2764A>G p.S922G | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as COSV100316353; called by muse, mutect2, varscan2
- CLDN16 | c.337A>G p.K113E | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs376431300, CM116890; called by muse, mutect2, varscan2
- CNTNAP5 | c.2702C>A p.S901* | Nonsense Mutation (SNP) | VAF 30/514 reads (6%) | catalogued as COSV70472877; called by muse, mutect2
- DCC | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 20/193 reads (10%) | catalogued as COSV100497982, COSV59093836; called by muse, mutect2
- DGAT2L6 | c.802G>T p.G268C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145712346; called by muse, mutect2, varscan2
- DLAT | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1555179651; called by muse, mutect2, varscan2
- DNAH8 | c.12533T>C p.V4178A | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as rs1221115991, COSV100543162; called by muse, mutect2
- DSCAM | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 72/260 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs755881168, COSV68024346; called by muse, mutect2, varscan2
- ECT2 | c.1519G>T p.D507Y (on ENST00000392692 / NM_001349098.2; = p.D476Y on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1208066079; called by muse, mutect2, varscan2
- ELAVL2 | c.496A>T p.R166W | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56356678; called by muse, mutect2, varscan2
- EML1 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs749083976, COSV51747244; called by muse, mutect2, varscan2
- FAT3 | c.307T>C p.C103R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53185387; called by muse, mutect2, varscan2
- FLG | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as COSV64249223; called by muse, mutect2, varscan2
- FNTA | c.269T>G p.I90S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100172549; called by muse, mutect2
- GP9 | c.184A>C p.S62R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as rs1267634927; called by muse, mutect2
- H1-1 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1198024711; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1843G>A p.G615S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs1345732673; called by muse, mutect2, varscan2
- IMMT | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs768354546; called by muse, mutect2, varscan2
- ITGAX | c.2198G>T p.R733L | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs761201188, COSV51643111; called by muse, mutect2, varscan2
- KCND2 | c.1717C>A p.R573= | Splice Region (SNP) | VAF 12/30 reads (40%) | catalogued as rs775854692, COSV58576213; called by muse, mutect2, varscan2
- KDR | c.1157T>C p.M386T | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs949197675, COSV55779451; called by muse, mutect2, varscan2
- KLHL1 | c.1179C>A p.D393E | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.085); catalogued as COSV100916966; called by muse, mutect2, varscan2
- KRTAP5-3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 29/207 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.222); catalogued as COSV101294487; called by muse, mutect2, varscan2
- LAIR1 | c.823A>G p.M275V | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs760167614; called by muse, mutect2, varscan2
- LAMC1 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99280636; called by muse, mutect2, varscan2
- LRRC3 | c.723G>C p.K241N | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99381681; called by muse, mutect2
- MEGF10 | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99174742, COSV99175250; called by muse, mutect2, varscan2
- MPEG1 | c.85G>T p.V29F | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99914963; called by muse, mutect2
- MUC17 | c.4517T>A p.I1506N | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs773540811, COSV60285850; called by muse, mutect2, varscan2
- MYO3A | c.2596G>T p.V866L | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56333440; called by muse, mutect2, varscan2
- NALCN | c.3227G>T p.R1076M | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.333); catalogued as rs1437183994; called by muse, mutect2, varscan2
- NEUROD4 | c.877G>T p.V293L | Missense Mutation (SNP) | VAF 141/537 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV54470829; called by muse, mutect2, varscan2
- NFASC | c.3221C>A p.T1074K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58361685; called by muse, mutect2, varscan2
- NLRP9 | c.1382G>C p.R461P | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.425); catalogued as rs758078069, COSV100242391, COSV100242973; called by muse, mutect2, varscan2
- NOTCH1 | c.7148A>G p.Q2383R | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.528); catalogued as rs1281553206; called by muse, mutect2, varscan2
- OR2T4 | c.611G>T p.R204L | Missense Mutation (SNP) | VAF 34/253 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV63544854; called by muse, mutect2, varscan2
- OR4K13 | c.811C>A p.L271I | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.768); catalogued as rs756620210, COSV59860515; called by muse, mutect2
- OR5B17 | c.68T>C p.V23A | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV62160625; called by muse, mutect2
- OR6N1 | c.111G>C p.M37I | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV58647755, COSV58650332; called by muse, mutect2, varscan2
- OR8K5 | c.832T>C p.Y278H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1346151014; called by muse, varscan2
- OR8K5 | c.801C>A p.F267L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV100537146, COSV100537280; called by muse, varscan2
- PAPPA2 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs375011994, COSV62779185; called by muse, mutect2, varscan2
- PAQR3 | c.811G>T p.G271* | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | catalogued as rs754070447; called by muse, mutect2, varscan2
- PCCA | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1192444349, COSV66198474; called by muse, varscan2
- PDE4DIP | c.5284C>A p.P1762T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.43); catalogued as COSV100520806; called by muse, mutect2, varscan2
- PIK3CB | c.1105G>C p.V369L | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.04); catalogued as rs759331142, COSV56683739; called by muse, mutect2
- PIK3R4 | c.2110A>G p.T704A | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1287558740; called by muse, mutect2, varscan2
- PKD2L1 | c.349+1G>A p.X117_splice | Splice Site (SNP) | VAF 11/63 reads (17%) | catalogued as rs556490027, COSV100559289; called by muse, mutect2, varscan2
- POM121L12 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as rs750523098, COSV101375017; called by muse, mutect2
- PRL | c.17C>A p.S6* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as rs1019269066, COSV100122987; called by muse, mutect2, varscan2
- RABEP2 | c.1538G>T p.R513L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs369691572; called by muse, mutect2, varscan2
- RELN | c.2738G>C p.R913P | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs764757536; called by muse, mutect2, varscan2
- RSPH10B | c.1689C>G p.Y563* | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | catalogued as COSV100521204; called by muse, varscan2
- RTN1 | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV50720778; called by muse, mutect2
- SAMD9L | c.1442G>T p.W481L | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs763034101, COSV59080895, COSV59080935; called by muse, mutect2, varscan2
- SERINC2 | c.810G>T p.Q270H (on ENST00000373709 / NM_178865.5; = p.Q274H on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101036882; called by muse, mutect2, varscan2
- TAF1L | c.1327A>G p.K443E | Missense Mutation (SNP) | VAF 97/232 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); catalogued as rs1367392431; called by muse, mutect2, varscan2
- TMEM176A | c.257C>A p.S86* | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as rs750535260, COSV50241058; called by muse, mutect2, varscan2
- TMEM64 | c.796-1G>T p.X266_splice | Splice Site (SNP) | VAF 18/62 reads (29%) | catalogued as COSV101375986; called by muse, mutect2, varscan2
- TNKS | c.3805G>T p.A1269S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60067648; called by muse, mutect2, varscan2
- TRIM48 | c.579-1G>T p.X193_splice | Splice Site (SNP) | VAF 14/46 reads (30%) | catalogued as rs750079377, COSV101338176; called by muse, mutect2, varscan2
- U2SURP | c.2089G>A p.A697T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as rs1364619257, COSV101204322, COSV67532018; called by muse, mutect2
- ZFHX4 | c.5167C>A p.P1723T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50512080, COSV51476340; called by muse, mutect2, varscan2
- ZNF430 | c.869G>C p.R290T | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV55110790, COSV55113742; called by muse, mutect2, varscan2
- ZNF479 | c.861C>A p.H287Q | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100482438; called by muse, mutect2
- ZNF536 | c.2844A>T p.K948N | Missense Mutation (SNP) | VAF 14/265 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100834607, COSV62834050; called by muse, mutect2
- ZNF585B | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as rs758906949, COSV57215029; called by muse, mutect2
- ZNF711 | c.623-1G>T p.X208_splice | Splice Site (SNP) | VAF 6/13 reads (46%) | catalogued as COSV99340617; called by muse, mutect2, varscan2
- ADHFE1 | c.1030A>T p.K344* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- AIM2 | c.520C>A p.Q174K | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ALPK1 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP13A5 | c.3079A>T p.N1027Y | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ATP2C2 | c.2465T>A p.F822Y | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ATP6V0A1 | c.2500A>T p.K834* (on ENST00000343619 / NM_001378531.1; = p.K828* on NM_005177.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 44/164 reads (27%) | called by muse, mutect2, varscan2
- B3GAT1 | c.140C>G p.T47R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- B4GALT1 | c.330dup p.A111Rfs*2 | Frame Shift Ins (INS) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- BICRAL | c.2603G>C p.G868A | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BRINP2 | c.1967G>C p.S656T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CD164L2 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT tolerated (0.35); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CD36 | c.885_886del p.P296Ifs*9 | Frame Shift Del (DEL) | VAF 34/129 reads (26%) | called by mutect2, pindel, varscan2
- CDC20B | c.812_813del p.L271Hfs*3 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by pindel, varscan2
- CDH9 | c.1254G>C p.K418N | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CETP | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CHRM2 | c.874G>C p.V292L | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2
- CHRNB4 | c.1027A>T p.T343S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CNR1 | c.1291T>A p.C431S | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CR1L | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRYZL1 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CST11 | c.301A>T p.N101Y | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DGKB | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- DMRTB1 | c.1023_1024del p.D342Lfs*30 | Frame Shift Del (DEL) | VAF 55/214 reads (26%) | called by mutect2, pindel, varscan2
- DNAJC1 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EBF3 | c.967G>T p.V323F (on ENST00000355311 / NM_001375392.1; = p.V314F on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ELAVL4 | c.237A>T p.R79S | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- EPDR1 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPPK1 | c.900C>A p.S300R | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- FAM135B | c.2851A>C p.T951P | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- FBXO31 | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXO34 | c.596T>C p.V199A | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FRMD3 | c.1360C>T p.L454F | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GDF5 | c.262C>G p.Q88E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GIT1 | c.1920_1921del p.S641Hfs*28 | Frame Shift Del (DEL) | VAF 50/186 reads (27%) | called by mutect2, pindel, varscan2
- GOLGB1 | c.4960G>T p.E1654* | Nonsense Mutation (SNP) | VAF 28/141 reads (20%) | called by muse, mutect2, varscan2
- GPAM | c.910C>A p.L304I | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- GPR142 | c.224A>T p.D75V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); called by muse, mutect2
- GUCY2C | c.2195C>A p.P732Q | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GUCY2C | c.2194C>G p.P732A | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- HRNR | c.3280_3281del p.A1094* | Frame Shift Del (DEL) | VAF 71/374 reads (19%) | called by mutect2, pindel, varscan2
- IGKV3D-11 | c.278T>G p.L93R | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- INSR | c.4006C>T p.Q1336* | Nonsense Mutation (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- INVS | c.1591_1592del p.A531Ffs*4 | Frame Shift Del (DEL) | VAF 18/178 reads (10%) | called by mutect2, varscan2
- IQUB | c.1035A>G p.I345M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- ITGAX | c.1384C>T p.L462F | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JARID2 | c.3211A>G p.K1071E | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.112); called by muse, mutect2
- KCNQ3 | c.2463T>G p.N821K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- KCNRG | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- KIDINS220 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- L3MBTL4 | c.193G>C p.A65P | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- LCT | c.3691G>C p.E1231Q | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LCT | c.1345_1369del p.Q449Gfs*24 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | called by mutect2, pindel
- MAN2B2 | c.1520G>C p.G507A | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MDGA1 | c.625T>A p.Y209N | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- MEF2C | c.360T>G p.I120M | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MGAT4C | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- MIPOL1 | c.773T>A p.I258K | Missense Mutation (SNP) | VAF 119/213 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTERF4 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MYH7 | c.5059G>A p.E1687K | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); called by muse, mutect2
- NEB | c.4220A>T p.Q1407L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NNMT | c.600G>T p.K200N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- NOVA1 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 117/227 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR10G8 | c.497C>A p.P166H | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR10K1 | c.529T>A p.F177I | Missense Mutation (SNP) | VAF 68/286 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- OR13C8 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- OR2L3 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- OR9G4 | c.768G>T p.L256F | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAAF1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.112); called by muse, mutect2
- PHF19 | c.1412G>A p.G471D | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); called by muse, mutect2
- PHF2 | c.1698G>A p.K566= | Splice Region (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- PKP2 | c.503A>G p.Y168C | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- PRLR | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- RC3H1 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RLN1 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- SAE1 | c.875_878+4del p.X292_splice | Splice Site (DEL) | VAF 18/140 reads (13%) | called by mutect2, pindel, varscan2
- SAMD9 | c.2554G>T p.A852S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SEL1L2 | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SERINC2 | c.811G>T p.A271S (on ENST00000373709 / NM_178865.5; = p.A275S on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SGCA | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- SLC15A2 | c.37_38del p.L13Ffs*7 | Frame Shift Del (DEL) | VAF 96/308 reads (31%) | called by pindel, varscan2
- SLC25A5 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); called by muse, varscan2
- SLCO1C1 | c.2126A>T p.E709V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); called by muse, mutect2
- SLITRK4 | c.539T>C p.L180S | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNRPN | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); called by muse, mutect2
- SNX16 | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); called by muse, mutect2
- SPTA1 | c.7091dup p.A2365Gfs*44 | Frame Shift Ins (INS) | VAF 15/84 reads (18%) | called by mutect2, pindel, varscan2
- SYNE1 | c.13961T>G p.V4654G (on ENST00000367255 / NM_182961.4; = p.V4583G on NM_033071.3) | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TAF1L | c.2309C>A p.P770Q | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- THAP6 | c.14G>T p.C5F | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM131 | c.2738C>A p.S913* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- TRAV10 | c.164G>C p.R55T | Missense Mutation (SNP) | VAF 108/216 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- TRIM47 | c.1300A>T p.S434C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- VPS13B | c.8711C>T p.P2904L | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.024); called by muse, mutect2
- WDR17 | c.2024C>A p.S675Y | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBBX | c.997C>G p.Q333E | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZBBX | c.7A>G p.R3G | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZHX2 | c.23C>A p.T8K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF624 | c.563A>G p.Q188R | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ZNF665 | c.1700G>C p.G567A (on ENST00000600412; = p.G632A on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF804B | c.101C>G p.P34R | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- ABCC8 | c.1197T>A p.I399= | Silent (SNP) | VAF 45/145 reads (31%) | called by muse, mutect2, varscan2
- B3GAT1 | c.240C>A p.S80= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- CCDC171 | c.942T>A p.A314= | Silent (SNP) | VAF 33/65 reads (51%) | called by muse, mutect2, varscan2
- CCDC191 | c.9G>A p.L3= | Silent (SNP) | VAF 11/133 reads (8%) | called by muse, mutect2
- CGN | c.2013C>T p.V671= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as rs201119742; called by mutect2, varscan2
- CUL5 | c.855C>A p.I285= | Silent (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2, varscan2
- DNAH5 | c.3141G>A p.G1047= | Silent (SNP) | VAF 43/150 reads (29%) | called by muse, mutect2, varscan2
- DSCAM | c.3150C>T p.T1050= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs1418597590; called by muse, mutect2, varscan2
- F5 | c.1794T>A p.T598= | Silent (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- F5 | c.600G>A p.E200= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100889203; called by muse, mutect2, varscan2
- FAM120AOS | c.678G>A p.V226= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs771489242; called by muse, mutect2, varscan2
- GREM1 | c.546T>C p.D182= | Silent (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- IGKV6D-21 | c.120C>A p.I40= | Silent (SNP) | VAF 9/20 reads (45%) | called by mutect2, varscan2
- INAVA | c.1524C>T p.P508= | Silent (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- KIF1A | c.1014C>T p.Y338= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs1237938827, COSV57489021; called by muse, mutect2, varscan2
- KNSTRN | c.120G>A p.A40= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs751927888; called by muse, mutect2, varscan2
- MAPT | c.1896G>A p.K632= (on ENST00000262410 / NM_001377265.1; = p.K240= on NM_005910.5) | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- MTCL1 | c.3330G>C p.R1110= (on ENST00000306329 / NM_001378206.1; = p.R791= on NM_015210.4) | Silent (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- NAPRT | c.1242G>A p.K414= | Silent (SNP) | VAF 14/89 reads (16%) | called by muse, mutect2, varscan2
- NEFM | c.765G>A p.T255= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV55332989; called by muse, mutect2, varscan2
- OR10J3 | c.102T>A p.T34= | Silent (SNP) | VAF 20/268 reads (7%) | called by muse, mutect2
- OR11H1 | c.925C>T p.L309= | Silent (SNP) | VAF 28/188 reads (15%) | catalogued as COSV99079129; called by mutect2, varscan2
- OR2C3 | c.222C>T p.F74= | Silent (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- OR52A5 | c.255C>A p.G85= | Silent (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2
- PCDHGA5 | c.1008A>T p.T336= | Silent (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- PCED1B | c.969C>A p.P323= | Silent (SNP) | VAF 20/145 reads (14%) | catalogued as COSV71394994; called by muse, mutect2, varscan2
- PCNX2 | c.3405C>T p.A1135= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs753050544, COSV50780698, COSV50789089; called by muse, mutect2, varscan2
- POLR3F | c.816A>T p.A272= | Silent (SNP) | VAF 90/389 reads (23%) | catalogued as rs1470434304; called by muse, mutect2, varscan2
- PPP1CA | c.309C>G p.T103= | Silent (SNP) | VAF 10/113 reads (9%) | catalogued as COSV100334822; called by muse, mutect2
- PPP1R12C | c.1755G>T p.A585= | Silent (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- PTGER3 | c.1125C>A p.P375= | Silent (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- PTPRD | c.4644G>T p.P1548= | Silent (SNP) | VAF 25/69 reads (36%) | called by muse, mutect2, varscan2
- RABEP2 | c.1539G>T p.R513= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- SCN8A | c.5409T>C p.I1803= | Silent (SNP) | VAF 5/102 reads (5%) | catalogued as COSV100633177; called by muse, mutect2
- SEMA3E | c.876C>G p.L292= | Silent (SNP) | VAF 39/135 reads (29%) | called by muse, mutect2, varscan2
- SLC5A11 | c.792G>A p.P264= | Silent (SNP) | VAF 25/197 reads (13%) | catalogued as rs201711094, COSV61739763; called by muse, mutect2, varscan2
- SLC8A2 | c.285G>T p.A95= | Silent (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- SUPT6H | c.4776C>T p.G1592= | Silent (SNP) | VAF 19/143 reads (13%) | catalogued as rs771684139; called by muse, mutect2, varscan2
- SYT7 | c.879C>T p.L293= | Silent (SNP) | VAF 45/358 reads (13%) | called by muse, mutect2, varscan2
- TEP1 | c.4068G>A p.K1356= | Silent (SNP) | VAF 91/168 reads (54%) | called by muse, mutect2, varscan2
- TGM4 | c.1894C>T p.L632= | Silent (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- TMEM106A | c.516G>A p.V172= | Silent (SNP) | VAF 33/202 reads (16%) | catalogued as rs747453506; called by muse, mutect2, varscan2
- TMEM64 | c.1039C>T p.L347= | Silent (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- VAV3 | c.2097G>A p.R699= | Silent (SNP) | VAF 5/91 reads (5%) | called by muse, mutect2
- ZIC4 | c.576A>G p.V192= | Silent (SNP) | VAF 51/202 reads (25%) | called by muse, mutect2, varscan2
- ZNF704 | c.456C>T p.D152= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs1207027856; called by muse, mutect2, varscan2
- ZPR1 | c.516T>C p.A172= | Silent (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73845966 G>A | 5'Flank (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- CCDC34 | c.606+64A>G | Intron (SNP) | VAF 8/61 reads (13%) | catalogued as rs1199563995; called by muse, mutect2, varscan2
- GNAO1 | c.723+6943C>A | Intron (SNP) | VAF 7/19 reads (37%) | catalogued as rs1443040664; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.291+11153C>A | Intron (SNP) | VAF 10/38 reads (26%) | catalogued as COSV61841911; called by muse, mutect2, varscan2
- LINC02145 | n.113A>C | RNA (SNP) | VAF 9/139 reads (6%) | called by muse, mutect2
- MUCL3 | c.947-38A>T | Intron (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- NRG1 | c.502+30851G>T | Intron (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20895900 G>T | 5'Flank (SNP) | VAF 16/93 reads (17%) | called by muse, mutect2, varscan2
- SNX29P2 | n.967G>A | RNA (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
